Gene-level copy-number profile of tumor specimen TCGA-AG-A014-01A from TCGA case TCGA-AG-A014, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 86.8 years (31,718 days).
Specimen TCGA-AG-A014-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.d21d9245-bfda-4a79-9394-1d8a6951adc9.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AG-A014-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 403 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fc212773-4981-4edf-b1f0-df7cdad038ff

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 523; copy number 2: 5,266; copy number 3: 5,081; copy number 4: 32,216; copy number 5: 6,257; copy number 6: 5,808; copy number 7: 1,700; copy number 8: 1,094; copy number 9: 469; copy number 10: 750; copy number 11: 861; copy number 12: 195.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-AG-A014-01): tumor purity 0.78, ploidy 3.67, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,275 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:66,767–34,249,958, 850 genes, copy number 9–10 (broad region; genes not listed).
- chr13:18,467,172–114,337,626, 1,391 genes, copy number 9–12 (broad region; genes not listed).
- chr20:52,671,735–55,684,915, 34 genes, copy number 9 (within-gene range 8–9): AL031674.1, AL161945.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, AL133335.2, PFDN4, AL133335.1, DOK5, RNU4ATAC7P, RPL12P4, LINC01440, LINC01441, AL160413.1.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
